CCDI case PBCGKZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0c7a26aa-851b-4a9b-b265-f4e4434d0f4b

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,845 days).

Biospecimens (3 samples)
- Sample 0DRKKC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRKKV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
